Gene-level copy-number profile of tumor specimen TARGET-10-PAUBTC-09A from TARGET case TARGET-10-PAUBTC, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 1.8 years (667 days).
Specimen TARGET-10-PAUBTC-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TARGET-ALL-P2.d1e08820-7ad9-5cbf-9a0b-0cc8ec050989.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TARGET-10-PAUBTC-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 356 have no estimate.
https://portal.gdc.cancer.gov/files/103f3acb-c94c-4069-8a56-53664a05dd11

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 569; copy number 1: 34; copy number 2: 59,313; copy number 3: 159; copy number 4: 188; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 49 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,340,998, 17 genes: TRGC2, TRGJ2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr7:38,345,030–38,345,499, 1 gene: TRGV5P.
- chr11:4,954,772–4,955,713, 1 gene: OR51A2.
- chr14:22,197,446–22,482,959, 1 gene (within-gene range 0–1): AC244502.1.
- chr14:22,304,054–22,490,553, 29 genes: TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDD3, TRDJ1, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54, TRAJ53, TRAJ52, TRAJ51, TRAJ50, TRAJ49, TRAJ48.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:4,233,288–4,288,083, 4 genes, copy number 5: SSU72P5, SSU72P2, SSU72P6, SSU72P4.

Autosomal genes at a single copy (total copy number 1): 34. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
